Somatic mutation profile of tumor specimen MP2PRT-PAUCXZ-TMP1-A (aliquot MP2PRT-PAUCXZ-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUCXZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,623 days).
Specimen MP2PRT-PAUCXZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2f1e50b-fa41-4f3a-aeb9-b7b6cfa4ac85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCXZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCXZ-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67be6849-0d44-4bd9-8e98-21bf532cacf7

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Del 1, Intron 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHV1-46 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1337425972; called by muse, varscan2
- KANK3 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.095); catalogued as rs1363911311, COSV58359490; called by muse, mutect2, varscan2
- PBX2 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 182/468 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1278122303, COSV100904009; called by muse, mutect2, varscan2
- ZBTB7A | c.522dup p.A175Rfs*19 | Frame Shift Ins (INS) | VAF 238/762 reads (31%) | catalogued as rs749935719; called by pindel, varscan2
- IGKV3OR2-268 | chr2:87339031 del CCTC | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by pindel, varscan2
- ARFGEF3 | c.6156G>A p.E2052= | Silent (SNP) | VAF 44/606 reads (7%) | called by muse, mutect2
- TAB2 | c.639C>T p.I213= | Silent (SNP) | VAF 126/325 reads (39%) | called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106511116 ins TCTAGG | 5'Flank (INS) | VAF 12/26 reads (46%) | called by pindel, varscan2
- UNC13B | c.761+7140G>T | Intron (SNP) | VAF 94/225 reads (42%) | called by muse, mutect2, varscan2
